Somatic mutation profile of tumor specimen TCGA-BA-A6DF-01A (aliquot TCGA-BA-A6DF-01A-11D-A30E-08) from TCGA case TCGA-BA-A6DF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 80.2 years (29,283 days).
Specimen TCGA-BA-A6DF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f465d217-82c8-4da1-9367-a7b4ec6a6021.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A6DF-10A (Blood Derived Normal), aliquot TCGA-BA-A6DF-10A-01D-A30H-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1252761-756d-421b-80c1-df3d08672cb2

The open-access MAF lists 154 somatic variants for this specimen: 124 protein-altering or splice-affecting, 29 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 29, Nonsense Mutation 13, Frame Shift Del 5, In Frame Del 3, Frame Shift Ins 2, Splice Site 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155dup p.I386Hfs*56 | Frame Shift Ins (INS) | VAF 24/78 reads (31%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- FBXW7 | c.1393C>T p.R465C (on ENST00000281708 / NM_001349798.2; = p.R385C on NM_018315.5) | Missense Mutation (SNP) | VAF 33/199 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867384286, COSV55891008, COSV55897912, COSV99654845; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 14/87 reads (16%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2M | c.3413G>A p.G1138E | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT tolerated (0.28); PolyPhen benign (0.168); catalogued as rs1433020524, COSV100588905; called by muse, mutect2, varscan2
- ABCA1 | c.2059A>G p.I687V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.247); catalogued as rs1221290023, COSV101037491; called by muse, mutect2, varscan2
- ABCA2 | c.6815C>T p.T2272I (on ENST00000614293; = p.T2242I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99688271; called by muse, mutect2, varscan2
- ACACB | c.1807G>A p.A603T | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as rs375366307, COSV58134071; called by muse, mutect2, varscan2
- ACLY | c.1993G>A p.G665S | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100709857; called by muse, mutect2, varscan2
- ADCY9 | c.3029G>A p.G1010E | Missense Mutation (SNP) | VAF 39/220 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99570670; called by muse, mutect2, varscan2
- ADGRL1 | c.3407G>A p.R1136Q (on ENST00000340736 / NM_001008701.3; = p.R1131Q on NM_014921.5) | Missense Mutation (SNP) | VAF 22/148 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1044476697, COSV100529743; called by muse, mutect2, varscan2
- AHNAK | c.9373G>A p.V3125M | Missense Mutation (SNP) | VAF 82/481 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.967); catalogued as rs79187953; called by muse, mutect2, varscan2
- AK5 | c.94G>A p.E32K (on ENST00000354567 / NM_174858.3; = p.E6K on NM_012093.4) | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as rs377289573, COSV100481558; called by muse, mutect2, varscan2
- AKAP8L | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 46/313 reads (15%) | SIFT tolerated (0.81); PolyPhen benign (0.314); catalogued as COSV101275853; called by muse, mutect2, varscan2
- ANKRD27 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs745675301, COSV60129155; called by muse, mutect2, varscan2
- ATP1A1 | c.2296C>T p.R766C | Missense Mutation (SNP) | VAF 9/161 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99814707; called by muse, mutect2
- BRD8 | c.1253A>G p.D418G (on ENST00000254900 / NM_139199.2; = p.D491G on NM_006696.4) | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV99137431; called by muse, mutect2, varscan2
- BSN | c.8957G>A p.R2986H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1342869857, COSV99607102; called by muse, mutect2, varscan2
- BTBD16 | c.318G>C p.K106N | Missense Mutation (SNP) | VAF 59/259 reads (23%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.587); catalogued as COSV99585210; called by muse, mutect2, varscan2
- BTBD7 | c.1337A>T p.H446L | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.908); catalogued as COSV100598120; called by muse, mutect2, varscan2
- BTN3A3 | c.454A>T p.I152F | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as COSV99764847, COSV99765011; called by muse, varscan2
- CAMK2D | c.158G>A p.R53K | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.606); catalogued as COSV99594603; called by muse, mutect2, varscan2
- CBLIF | c.466C>T p.R156C | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.852); catalogued as rs374000712; called by muse, mutect2, varscan2
- CEP120 | c.1873G>A p.V625I | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs372774629, COSV100071213; called by muse, mutect2, varscan2
- CFAP91 | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.164); catalogued as COSV99847414; called by muse, mutect2
- CHSY3 | c.1312G>A p.E438K | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as rs959217312, COSV100519789; called by muse, mutect2
- CHUK | c.1533G>T p.W511C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100957258; called by muse, mutect2, varscan2
- CLMN | c.2210C>A p.A737D | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.454); catalogued as COSV100112794; called by muse, mutect2, varscan2
- CLMP | c.427C>G p.L143V | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV101507444; called by muse, mutect2, varscan2
- COL22A1 | c.3946C>A p.P1316T | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.812); catalogued as COSV100280224, COSV57325033; called by muse, mutect2, varscan2
- COL4A6 | c.4338A>C p.G1446= | Splice Region (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100564871; called by muse, mutect2, varscan2
- COL6A6 | c.1041C>A p.N347K | Missense Mutation (SNP) | VAF 37/285 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as COSV100650786; called by muse, mutect2, varscan2
- CPNE4 | c.976T>C p.S326P | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101456788; called by muse, mutect2, varscan2
- CRYGS | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.643); catalogued as rs764793775, COSV57192133; called by muse, mutect2, varscan2
- CYP27A1 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99298704; called by muse, mutect2, varscan2
- DCAF4L2 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 20/176 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1158634102, COSV60478459; called by muse, mutect2, varscan2
- DDX47 | c.482A>G p.K161R | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as COSV100774624; called by muse, mutect2, varscan2
- DDX47 | c.953T>C p.L318P | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV100774627; called by muse, mutect2, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 19/122 reads (16%) | catalogued as rs748318989; called by mutect2, varscan2
- DMD | c.7945C>T p.R2649W | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1015097529, COSV58945714; called by muse, mutect2, varscan2
- DNAH8 | c.10465C>T p.Q3489* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100546824; called by muse, mutect2
- DYRK1A | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 12/72 reads (17%) | catalogued as rs1555984143, COSV100118188; called by muse, mutect2, varscan2
- EFNB1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1251392015, COSV52661077; called by muse, mutect2, varscan2
- ELAVL1 | c.268A>C p.T90P | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as COSV100688478; called by muse, mutect2, varscan2
- EPB41L4B | c.1997C>T p.P666L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.121); catalogued as COSV63124420; called by muse, mutect2, varscan2
- FAM71B | c.52A>G p.M18V | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as rs763029396, COSV100262263; called by muse, mutect2, varscan2
- FN3KRP | c.919C>A p.L307M | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99485085; called by muse, mutect2, varscan2
- GALNT7 | c.631G>A p.V211I | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as rs146899388; called by muse, mutect2, varscan2
- GATA2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.579); catalogued as rs745439347, COSV62003624; called by muse, mutect2, varscan2
- GOLGA3 | c.2072C>T p.A691V | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as rs200184795; called by muse, mutect2
- GOLGB1 | c.6784C>T p.Q2262* | Nonsense Mutation (SNP) | VAF 10/73 reads (14%) | catalogued as COSV100511390; called by muse, mutect2, varscan2
- GPR6 | c.1008C>G p.I336M | Missense Mutation (SNP) | VAF 38/214 reads (18%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.954); catalogued as rs538325483, COSV99254488; called by muse, mutect2, varscan2
- GRIPAP1 | c.806C>G p.A269G | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.995); catalogued as COSV100904368; called by muse, mutect2, varscan2
- GRM3 | c.632C>T p.T211I | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862765; called by muse, mutect2, varscan2
- IQSEC1 | c.1295G>A p.R432Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.744); catalogued as rs565538660, COSV99832073, COSV99832244; called by muse, mutect2, varscan2
- JPH1 | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 23/132 reads (17%) | catalogued as COSV100646740; called by muse, mutect2, varscan2
- KDM3B | c.4976G>A p.R1659H | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58689567; called by muse, mutect2, varscan2
- KIF26B | c.548G>A p.R183H | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.29); catalogued as rs1362317958, COSV101313890, COSV68572384; called by muse, mutect2
- KIT | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as COSV99855108; called by muse, mutect2, varscan2
- KLHL32 | c.1396G>C p.V466L | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.05); catalogued as COSV100987457; called by muse, mutect2, varscan2
- KMT2D | c.7138C>T p.Q2380* | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as COSV56429213; called by muse, mutect2, varscan2
- LIX1 | c.244C>T p.Q82* | Nonsense Mutation (SNP) | VAF 20/102 reads (20%) | catalogued as COSV99172952; called by muse, mutect2, varscan2
- LMTK2 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs866500949, COSV99806622; called by muse, mutect2, varscan2
- LRRC42 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as COSV59961218; called by muse, mutect2, varscan2
- MAGEB3 | c.155A>C p.K52T | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.013); catalogued as COSV100854782, COSV64397302; called by muse, mutect2, varscan2
- MAPKAP1 | c.1465C>T p.R489* (on ENST00000265960 / NM_001006617.3; = p.R453* on NM_024117.3) | Nonsense Mutation (SNP) | VAF 16/107 reads (15%) | catalogued as COSV99784617; called by muse, mutect2, varscan2
- MEGF8 | c.8180G>T p.R2727L (on ENST00000251268 / NM_001271938.2; = p.R2660L on NM_001410.3) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.323); catalogued as rs759523264, COSV99238526; called by muse, mutect2
- MIDN | c.844G>A p.G282R | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99960368; called by muse, mutect2, varscan2
- MTMR8 | c.499G>T p.V167F | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.694); catalogued as COSV100878533; called by muse, mutect2, varscan2
- MUC16 | c.16477A>G p.S5493G | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV101201044; called by muse, mutect2, varscan2
- MUC3A | c.7190C>G p.T2397S | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT tolerated, low confidence (0.12); catalogued as rs1452516452; called by muse, mutect2, varscan2
- MYO7A | c.5032C>T p.R1678W | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.241); catalogued as rs921687836, COSV68684415; called by muse, mutect2, varscan2
- MYOD1 | c.452G>A p.R151H | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs1188761200, COSV51452860; called by muse, mutect2, varscan2
- NAALAD2 | c.1358G>A p.R453K | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.329); catalogued as COSV100428717; called by muse, mutect2
- NEK5 | c.1815T>G p.N605K | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.029); catalogued as COSV100839288; called by muse, mutect2, varscan2
- NELFA | c.557G>C p.R186P (on ENST00000542778; = p.R175P on NM_005663.5) | Missense Mutation (SNP) | VAF 73/378 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100425080; called by muse, mutect2, varscan2
- NME7 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV100891134; called by muse, mutect2, varscan2
- NOTCH1 | c.1147G>T p.E383* | Nonsense Mutation (SNP) | VAF 4/11 reads (36%) | catalogued as COSV53074387, COSV99490932; called by muse, varscan2
- NRK | c.1235C>A p.A412E | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs773752651, COSV99688885; called by muse, mutect2, varscan2
- NSD2 | c.2765T>G p.F922C | Missense Mutation (SNP) | VAF 77/502 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100373749; called by muse, mutect2, varscan2
- NXPH1 | c.470C>A p.S157* | Nonsense Mutation (SNP) | VAF 15/51 reads (29%) | catalogued as COSV101339772; called by muse, mutect2, varscan2
- OR52M1 | c.170T>A p.L57Q | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100798607; called by muse, mutect2, varscan2
- OR5D16 | c.820A>G p.K274E | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as COSV101004109; called by muse, mutect2, varscan2
- PCDHA10 | c.295G>A p.V99M | Missense Mutation (SNP) | VAF 46/291 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.298); catalogued as COSV100253389; called by muse, mutect2, varscan2
- PCDHB3 | c.691C>A p.Q231K | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV99166319; called by muse, mutect2
- PCLO | c.4148C>A p.T1383N | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV100436512; called by muse, mutect2, varscan2
- PDGFB | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.89); catalogued as rs1237058477, COSV100483586; called by muse, mutect2, varscan2
- PJA1 | c.1291G>A p.A431T (on ENST00000361478 / NM_145119.4; = p.A243T on NM_022368.5) | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.956); catalogued as COSV100824786; called by muse, mutect2, varscan2
- PKDREJ | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV53546250; called by muse, mutect2, varscan2
- PLXNA3 | c.3746C>T p.A1249V | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1557207929, COSV100860192; called by muse, mutect2
- PNPLA4 | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 23/101 reads (23%) | catalogued as COSV101124416; called by muse, mutect2, varscan2
- PRKCG | c.31T>A p.S11T | Missense Mutation (SNP) | VAF 49/246 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.001); catalogued as COSV99669429; called by muse, mutect2, varscan2
- PSG11 | c.293G>A p.R98Q | Missense Mutation (SNP) | VAF 83/401 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs768654374, COSV60454253; called by muse, mutect2, varscan2
- PUF60 | c.850G>T p.V284L (on ENST00000526683 / NM_001362896.2; = p.V267L on NM_014281.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.22); catalogued as COSV100253978; called by muse, mutect2
- RAD54L2 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99621703; called by muse, mutect2, varscan2
- RAP1B | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51667594; called by muse, mutect2, varscan2
- RELCH | c.3585G>C p.L1195F | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV99902644; called by muse, mutect2, varscan2
- RGL3 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 75/357 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV100710614; called by muse, mutect2, varscan2
- RSU1 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 6/80 reads (8%) | catalogued as COSV61709317; called by muse, mutect2
- RYR1 | c.11449G>C p.D3817H | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV100616688; called by muse, mutect2
- RYR2 | c.10930T>A p.L3644I | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.113); catalogued as COSV100772242; called by muse, mutect2, varscan2
- SCAP | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV99653177; called by muse, mutect2, varscan2
- SCUBE2 | c.1940G>T p.R647I | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.192); catalogued as COSV100496878; called by muse, mutect2, varscan2
- SLC12A9 | c.203G>T p.G68V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99308105; called by muse, mutect2, varscan2
- SLC6A7 | c.412G>T p.A138S | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.864); catalogued as COSV100046499, COSV57940420, COSV57940921; called by muse, mutect2, varscan2
- TET2 | c.2491C>T p.Q831* | Nonsense Mutation (SNP) | VAF 10/66 reads (15%) | catalogued as COSV54395440; called by muse, mutect2, varscan2
- TIE1 | c.686C>A p.P229Q | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.1); catalogued as COSV100992149; called by muse, mutect2, varscan2
- TMIGD2 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV100010465; called by muse, mutect2
- TOR3A | c.613C>A p.H205N | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100751392, COSV61680888; called by muse, mutect2, varscan2
- TRIP11 | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.466); catalogued as COSV99971066; called by muse, mutect2, varscan2
- TTN | c.12619G>C p.V4207L (on ENST00000591111; = p.V4161L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/130 reads (5%) | catalogued as COSV100625727; called by muse, mutect2
- VPS13B | c.979C>T p.Q327* | Nonsense Mutation (SNP) | VAF 5/45 reads (11%) | catalogued as COSV62022987; called by muse, mutect2
- WIPF3 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as rs754655046, COSV54210700; called by muse, mutect2, varscan2
- WNT6 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs766635655, COSV99293293; called by muse, mutect2, varscan2
- ZNF449 | c.327G>C p.Q109H | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100203046; called by muse, mutect2, varscan2
- ALDH1A2 | c.1107_1109del p.N369del | In Frame Del (DEL) | VAF 13/99 reads (13%) | called by pindel, varscan2
- APOO | c.80del p.K27Rfs*9 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- C1orf56 | c.785_787del p.C262_P263delinsS | In Frame Del (DEL) | VAF 73/205 reads (36%) | called by mutect2, pindel, varscan2
- CTCF | c.1820_1837+5del p.X607_splice | Splice Site (DEL) | VAF 18/127 reads (14%) | called by mutect2, pindel
- DCSTAMP | c.1130G>C p.W377S | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- FAT1 | c.9828del p.K3277Nfs*4 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- KMT2B | c.1656del p.K553Nfs*52 | Frame Shift Del (DEL) | VAF 7/34 reads (21%) | called by mutect2, pindel, varscan2
- MBLAC2 | c.482del p.Q161Rfs*36 | Frame Shift Del (DEL) | VAF 7/52 reads (13%) | called by mutect2, pindel
- NOA1 | c.1248_1250del p.E416del | In Frame Del (DEL) | VAF 18/94 reads (19%) | called by pindel, varscan2
- PTPN2 | c.459_474del p.T155Nfs*2 | Frame Shift Del (DEL) | VAF 9/73 reads (12%) | called by mutect2, pindel
- ACAN | c.4995A>G p.T1665= | Silent (SNP) | VAF 33/203 reads (16%) | catalogued as COSV100719018; called by muse, mutect2, varscan2
- AGO2 | c.354G>A p.T118= | Silent (SNP) | VAF 31/176 reads (18%) | catalogued as rs377556379, COSV99596239; called by muse, mutect2, varscan2
- ANKS1B | c.3429C>A p.L1143= (on ENST00000547776 / NM_152788.4; = p.L309= on NM_020140.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100228661; called by muse, mutect2, varscan2
- ARHGEF2 | c.2664C>T p.P888= (on ENST00000361247 / NM_001162383.2; = p.P860= on NM_004723.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 49/107 reads (46%) | catalogued as rs753546449, COSV58109877, COSV58115099; called by muse, mutect2, varscan2
- ASB5 | c.258G>A p.L86= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as COSV99642018; called by muse, mutect2, varscan2
- CCNB3 | c.2094G>A p.E698= | Silent (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99329602; called by muse, mutect2, varscan2
- DAB2IP | c.1383C>T p.A461= (on ENST00000408936; = p.A433= on NM_032552.3) | Silent (SNP) | VAF 34/103 reads (33%) | catalogued as rs375557765; called by muse, mutect2, varscan2
- DNHD1 | c.768T>C p.V256= | Silent (SNP) | VAF 6/59 reads (10%) | catalogued as COSV99600775; called by muse, mutect2
- DUOX2 | c.906G>T p.L302= | Silent (SNP) | VAF 11/67 reads (16%) | catalogued as COSV100545944; called by muse, mutect2, varscan2
- FADS2 | c.180C>T p.I60= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV53896492; called by muse, mutect2, varscan2
- FN3KRP | c.405G>A p.E135= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV99485079; called by muse, varscan2
- GPC2 | c.180G>A p.R60= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as rs767995820, COSV99445012; called by muse, mutect2, varscan2
- KLF10 | c.420C>T p.S140= | Silent (SNP) | VAF 57/163 reads (35%) | catalogued as rs147912564, COSV99574905; called by muse, mutect2, varscan2
- MYH7 | c.2388C>T p.L796= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as rs397516144, COSV100806481; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHGA5 | c.1779G>A p.A593= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs758409280, COSV54002020; called by muse, mutect2, varscan2
- PER1 | c.1143G>T p.L381= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100424793; called by muse, mutect2, varscan2
- PEX6 | c.1845C>T p.G615= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs752085006, COSV99769939; called by muse, mutect2, varscan2
- POLG2 | c.84G>A p.G28= | Silent (SNP) | VAF 24/125 reads (19%) | catalogued as COSV99858202; called by muse, mutect2, varscan2
- POLR2A | c.324C>T p.R108= | Silent (SNP) | VAF 31/203 reads (15%) | catalogued as rs1236429982, COSV100496203; called by muse, mutect2, varscan2
- RYR2 | c.3237C>T p.S1079= | Silent (SNP) | VAF 23/66 reads (35%) | catalogued as rs770116364, COSV63676503; called by muse, mutect2, varscan2
- SEPTIN3 | c.930G>A p.Q310= | Silent (SNP) | VAF 16/92 reads (17%) | catalogued as COSV99352329; called by muse, mutect2, varscan2
- SPG11 | c.7125C>A p.S2375= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99969333; called by muse, mutect2
- TECPR1 | c.513C>T p.S171= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as rs1194599660, COSV101130692; called by muse, mutect2, varscan2
- THOC2 | c.1212T>A p.A404= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV99833996; called by muse, varscan2
- TMC7 | c.576G>A p.T192= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs111625310, COSV58588648; called by muse, mutect2, varscan2
- UBTF | c.567T>C p.N189= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as COSV100256092; called by muse, mutect2, varscan2
- ZACN | c.345C>G p.L115= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100135621, COSV58038211; called by muse, mutect2
- ZNF324 | c.741C>A p.G247= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99543445; called by muse, mutect2, varscan2
- ZXDA | c.921C>T p.C307= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs778310777, COSV100699368; called by muse, mutect2
- NBPF7 | n.183C>T | RNA (SNP) | VAF 42/118 reads (36%) | catalogued as rs761470346; called by muse, mutect2, varscan2
